Somatic mutation profile of tumor specimen TCGA-44-5644-01A (aliquot TCGA-44-5644-01A-21D-2036-08) from TCGA case TCGA-44-5644, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 51.0 years (18,644 days).
Specimen TCGA-44-5644-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ccf6b28-a355-4fe5-b8f6-8f510381a6f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-5644-10A (Blood Derived Normal), aliquot TCGA-44-5644-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71379a24-2b0a-4898-8f23-a773d1809cfc

The open-access MAF lists 1,033 somatic variants for this specimen: 805 protein-altering or splice-affecting, 211 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 685, Silent 211, Nonsense Mutation 52, Frame Shift Del 26, Splice Site 23, Intron 10, Frame Shift Ins 8, Splice Region 7, RNA 4, In Frame Del 2, 5'UTR 2, Nonstop Mutation 1.

Variants (750 of 1,033; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.5666G>T p.C1889F | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1566899500, CM098699, CM100479, COSV57324050; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTHFR | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs786204023, CM155629, COSV64877535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTRR | c.1540G>A p.G514R (on ENST00000264668; = p.G487R on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/158 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853061, CM992189, COSV52945418; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.326T>G p.F109C | Missense Mutation (SNP) | VAF 57/70 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796722, COSV52725602, COSV52838438; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1420T>A p.Y474N | Missense Mutation (SNP) | VAF 78/93 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55294755; called by muse, mutect2, varscan2
- AACS | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs552206706, COSV55538790, COSV99908323; called by muse, mutect2, varscan2
- ABCA13 | c.14118G>T p.K4706N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV68948915; called by muse, mutect2, varscan2
- ABI3 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 58/74 reads (78%) | SIFT tolerated (0.94); PolyPhen benign (0.306); catalogued as COSV56800873; called by muse, mutect2, varscan2
- ABI3BP | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV52543984; called by mutect2, varscan2
- ABL2 | c.488C>A p.T163N (on ENST00000502732 / NM_007314.4; = p.T148N on NM_005158.5) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61017876; called by muse, mutect2, varscan2
- ACO1 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs551232686, COSV59382286; called by muse, mutect2, varscan2
- ACSM5 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs1304695952, COSV59373285; called by muse, mutect2, varscan2
- ACTG2 | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV61829118; called by muse, mutect2, varscan2
- ADAD1 | c.1672C>A p.Q558K | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV56645361; called by muse, mutect2, varscan2
- ADAM11 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 57/77 reads (74%) | catalogued as COSV52348115; called by muse, mutect2, varscan2
- ADAM23 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs372261190; called by muse, mutect2
- ADAMTS5 | c.2293G>T p.A765S | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs147165669; called by muse, mutect2, varscan2
- ADAMTS5 | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53176287, COSV53181881; called by muse, mutect2, varscan2
- ADCY1 | c.1550T>A p.M517K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV52038672; called by muse, mutect2, varscan2
- ADCY2 | c.2456T>C p.V819A | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV57885777; called by muse, mutect2, varscan2
- ADCY2 | c.2678T>C p.I893T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57885794; called by muse, mutect2, varscan2
- ADGRA3 | c.3685G>T p.E1229* | Nonsense Mutation (SNP) | VAF 21/109 reads (19%) | catalogued as COSV51565921; called by muse, varscan2
- ADGRB1 | c.3694G>T p.A1232S | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV60100523; called by muse, mutect2, varscan2
- ADGRF5 | c.3081G>T p.L1027F | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51937287; called by muse, mutect2, varscan2
- ADGRG6 | c.3509C>T p.S1170L | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51595276, COSV51596611, COSV99746362; called by muse, mutect2, varscan2
- ADGRL3 | c.476G>T p.C159F (on ENST00000506720 / NM_001322402.2; = p.C91F on NM_015236.6) | Missense Mutation (SNP) | VAF 94/122 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72269718; called by muse, mutect2, varscan2
- AEBP1 | c.2970C>G p.I990M | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56259535; called by muse, mutect2, varscan2
- AEBP2 | c.1173A>G p.L391= | Splice Region (SNP) | VAF 9/16 reads (56%) | catalogued as COSV56864999; called by muse, mutect2, varscan2
- AGPAT1 | c.334G>T p.G112W | Missense Mutation (SNP) | VAF 97/121 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61248199; called by muse, mutect2, varscan2
- AGRN | c.2659G>T p.G887C | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373631709; called by muse, varscan2
- AIFM3 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.634); catalogued as COSV59001451; called by muse, mutect2, varscan2
- AK5 | c.700-2A>T p.X234_splice (on ENST00000354567 / NM_174858.3; = p.X208_splice on NM_012093.4) | Splice Site (SNP) | VAF 22/59 reads (37%) | catalogued as COSV60977335; called by muse, mutect2, varscan2
- AKAP1 | c.1039G>C p.A347P | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV58471558; called by muse, mutect2, varscan2
- AKAP10 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1355675469, COSV56732234; called by muse, mutect2, varscan2
- ALDH1A1 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 67/79 reads (85%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1057408909, COSV52792875; called by muse, mutect2, varscan2
- ALMS1 | c.4306G>T p.G1436C | Missense Mutation (SNP) | VAF 86/163 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.879); catalogued as COSV52515820; called by muse, mutect2, varscan2
- ALMS1 | c.6989G>T p.R2330M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52515830; called by muse, mutect2, varscan2
- AMER3 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV58468392; called by muse, mutect2, varscan2
- AMPH | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV57749717; called by muse, mutect2, varscan2
- ANGPT4 | c.253C>A p.Q85K | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV67922292; called by muse, varscan2
- ANK2 | c.10196C>A p.S3399* | Nonsense Mutation (SNP) | VAF 35/47 reads (74%) | catalogued as COSV52175126; called by muse, mutect2, varscan2
- ANKRD13B | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67474156; called by muse, mutect2, varscan2
- ANKRD13C | c.1496-1G>T p.X499_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99256039; called by muse, mutect2
- ANKRD17 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV58224274; called by muse, mutect2, varscan2
- ANKRD24 | c.3150G>T p.K1050N | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV53673154; called by muse, mutect2, varscan2
- ANO4 | c.1154+1G>T p.X385_splice (on ENST00000392977 / NM_001286615.2; = p.X350_splice on NM_178826.4) | Splice Site (SNP) | VAF 56/118 reads (47%) | catalogued as COSV54595143, COSV54604888; called by muse, mutect2, varscan2
- ANO4 | c.1738G>C p.E580Q (on ENST00000392977 / NM_001286615.2; = p.E545Q on NM_178826.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54591380, COSV54604896; called by muse, mutect2, varscan2
- APBB1 | c.1439A>G p.H480R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54978393; called by muse, mutect2, varscan2
- APOA4 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV63360894; called by muse, mutect2, varscan2
- APOA4 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV63360899; called by muse, varscan2
- APOB | c.8749G>A p.G2917S | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs1400060378, COSV51944219; called by muse, mutect2, varscan2
- APOB | c.3780G>T p.E1260D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.554); catalogued as rs1297997404, COSV51944232; called by muse, mutect2, varscan2
- ARC | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV63079061; called by muse, mutect2, varscan2
- ARHGAP32 | c.2119G>T p.E707* (on ENST00000310343 / NM_001378025.1; = p.E358* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 32/58 reads (55%) | catalogued as COSV100087028, COSV59852061; called by muse, mutect2, varscan2
- ARHGAP36 | c.495T>G p.F165L | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52269402; called by muse, mutect2, varscan2
- ARHGAP9 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV62723842; called by muse, mutect2, varscan2
- ARHGEF12 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63104717; called by muse, mutect2, varscan2
- ASPM | c.2035A>G p.R679G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54133895; called by muse, mutect2, varscan2
- ASTN1 | c.2650G>T p.E884* | Nonsense Mutation (SNP) | VAF 36/62 reads (58%) | catalogued as COSV56077042; called by muse, mutect2, varscan2
- ASTN1 | c.2471C>G p.A824G | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV56077053; called by muse, mutect2, varscan2
- ASTN1 | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 99/178 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.987); catalogued as COSV56077065; called by muse, mutect2, varscan2
- ASTN2 | c.2248T>G p.C750G (on ENST00000313400 / NM_001365069.1; = p.C699G on NM_014010.5) | Missense Mutation (SNP) | VAF 70/92 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57797905; called by muse, mutect2, varscan2
- ASXL3 | c.2091C>A p.N697K | Missense Mutation (SNP) | VAF 143/260 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV52472897; called by muse, mutect2, varscan2
- ATAD2 | c.1688A>G p.D563G | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54884058; called by muse, mutect2, varscan2
- ATP10B | c.1448T>A p.L483Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as COSV58779881; called by muse, mutect2, varscan2
- ATP2B1 | c.958C>A p.R320S | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV53810259, COSV53813059; called by muse, mutect2, varscan2
- ATP4A | c.302T>A p.V101D | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV52865150, COSV52869779; called by muse, mutect2, varscan2
- ATXN2L | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57374956; called by muse, mutect2, varscan2
- AVPR1A | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV54547383; called by muse, mutect2, varscan2
- AVPR1A | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV100146750; called by muse, mutect2, varscan2
- BAG6 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 103/116 reads (89%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV52993090; called by muse, mutect2, varscan2
- BCL9 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs782230804, COSV52347514; called by muse, mutect2, varscan2
- BCO2 | c.975G>C p.W325C | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63064200; called by muse, mutect2, varscan2
- BEND4 | c.886C>G p.P296A | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV72469244; called by muse, varscan2
- BEND6 | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV66069584; called by muse, mutect2, varscan2
- BICC1 | c.68G>T p.S23I | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.334); catalogued as COSV65856155, COSV65862677; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2413G>T p.A805S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778313769, COSV63246140; called by muse, mutect2, varscan2
- BLK | c.970C>A p.L324M | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52054092; called by muse, varscan2
- BMPR1A | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63135270; called by muse, mutect2, varscan2
- BOD1L1 | c.4751C>T p.T1584I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50029053; called by muse, mutect2, varscan2
- BRINP3 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66523548, COSV66544308; called by muse, mutect2
- BRWD3 | c.2659G>T p.D887Y | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100955939, COSV64751314; called by muse, mutect2, varscan2
- BTAF1 | c.4332G>T p.W1444C | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56436724; called by muse, mutect2, varscan2
- BTBD10 | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV53400344; called by muse, mutect2, varscan2
- BTBD3 | c.1174G>C p.G392R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54780425; called by muse, mutect2, varscan2
- C1QB | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as COSV59245744; called by muse, mutect2, varscan2
- C1QTNF9 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59657650; called by muse, mutect2, varscan2
- C1orf50 | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); catalogued as COSV65308313; called by muse, mutect2, varscan2
- C8orf34 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs138458632; called by muse, mutect2
- C9 | c.674A>T p.K225I | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV54679103; called by muse, mutect2
- CA8 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527113, COSV58773308; called by muse, mutect2, varscan2
- CABP1 | c.993G>A p.M331I (on ENST00000316803 / NM_001033677.1; = p.M128I on NM_004276.5) | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as COSV56459546; called by muse, mutect2, varscan2
- CACNA1E | c.971C>A p.A324D | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV100701174; called by muse, mutect2, varscan2
- CACNA1I | c.5487C>A p.F1829L | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV60813851; called by muse, mutect2, varscan2
- CACNB4 | c.1268T>A p.L423H | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV52398470; called by muse, mutect2, varscan2
- CACNG4 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50926257, COSV50927391; called by muse, mutect2, varscan2
- CADM3 | c.445A>T p.T149S (on ENST00000368125 / NM_001127173.3; = p.T183S on NM_021189.5) | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.593); catalogued as COSV63686480; called by muse, mutect2, varscan2
- CAPN10 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.548); catalogued as COSV54377887, COSV54378059; called by muse, mutect2, varscan2
- CCDC102B | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV60135938; called by muse, mutect2, varscan2
- CCDC136 | c.1394C>A p.A465D | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV52802338; called by muse, mutect2, varscan2
- CCDC148 | c.846_847insT p.T283Yfs*16 | Frame Shift Ins (INS) | VAF 21/54 reads (39%) | catalogued as COSV99319497; called by mutect2, pindel, varscan2
- CCDC198 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV53602016, COSV53602791; called by muse, mutect2, varscan2
- CCDC27 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99621920; called by muse, mutect2, varscan2
- CCDC50 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.37); catalogued as COSV101165231; called by muse, mutect2, varscan2
- CCDC54 | c.47T>A p.M16K | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV53759332; called by muse, mutect2, varscan2
- CCDC63 | c.846G>C p.R282S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV57529573; called by muse, mutect2, varscan2
- CCDC63 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.003); catalogued as COSV57407571; called by muse, mutect2, varscan2
- CCDC80 | c.2162T>A p.L721Q | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52818576; called by muse, mutect2, varscan2
- CCDC85A | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.344); catalogued as rs755801107, COSV68153691; called by muse, mutect2, varscan2
- CCER1 | c.370T>C p.C124R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62647780; called by muse, mutect2, varscan2
- CCKAR | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV55162683; called by muse, mutect2, varscan2
- CD200R1L | c.46+1G>T p.X16_splice | Splice Site (SNP) | VAF 45/91 reads (49%) | catalogued as COSV101236532; called by muse, mutect2, varscan2
- CD276 | c.1045A>T p.S349C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59204749; called by muse, mutect2, varscan2
- CDH19 | c.631A>T p.K211* | Nonsense Mutation (SNP) | VAF 27/48 reads (56%) | catalogued as COSV100050631, COSV100052056; called by muse, mutect2, varscan2
- CDH20 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV53013862, COSV53018396; called by muse, varscan2
- CDH20 | c.1378C>A p.H460N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV53013872; called by muse, varscan2
- CDH23 | c.6220C>T p.L2074F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as rs970644293, COSV104386326, COSV56477005; called by muse, mutect2, varscan2
- CDH7 | c.1273T>A p.F425I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59889747; called by muse, mutect2, varscan2
- CDK15 | c.931G>A p.E311K (on ENST00000652192 / NM_001366386.2; = p.E260K on NM_139158.2) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.138); catalogued as COSV53636253; called by muse, mutect2, varscan2
- CDK4 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56985870; called by muse, mutect2, varscan2
- CEP350 | c.4006C>G p.L1336V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV62606409; called by muse, mutect2, varscan2
- CEP350 | c.7070A>G p.K2357R | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV62606420; called by muse, mutect2, varscan2
- CEP43 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV62761235; called by muse, mutect2, varscan2
- CFAP54 | c.5949G>T p.E1983D | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.125); catalogued as COSV61571662; called by muse, mutect2, varscan2
- CFAP54 | c.7754T>A p.L2585H | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61573480; called by muse, mutect2, varscan2
- CFAP61 | c.2283C>G p.I761M | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.539); catalogued as COSV55620233, COSV55638487; called by muse, mutect2, varscan2
- CFAP70 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60285202; called by muse, mutect2, varscan2
- CFH | c.259C>G p.H87D | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV62778272; called by muse, mutect2, varscan2
- CFHR4 | c.1526C>A p.P509Q (on ENST00000367416 / NM_001201551.2; = p.P263Q on NM_006684.5) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368404578, COSV52232522; called by muse, mutect2, varscan2
- CHAT | c.1383-1G>T p.X461_splice | Splice Site (SNP) | VAF 17/23 reads (74%) | catalogued as COSV60328908; called by muse, mutect2, varscan2
- CHD6 | c.3701G>T p.R1234L | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV58559719; called by muse, mutect2, varscan2
- CHERP | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52226162; called by muse, mutect2, varscan2
- CHIT1 | c.365C>A p.S122* | Nonsense Mutation (SNP) | VAF 29/140 reads (21%) | catalogued as COSV55146544, COSV55148280; called by muse, mutect2, varscan2
- CHML | c.1264A>G p.I422V | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated (0.29); PolyPhen benign (0.149); catalogued as rs780997451, COSV59365951; called by muse, mutect2, varscan2
- CHRM2 | c.1144del p.E382Kfs*81 | Frame Shift Del (DEL) | VAF 23/108 reads (21%) | catalogued as COSV57765651; called by mutect2, pindel, varscan2
- CHRND | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51324639; called by muse, mutect2, varscan2
- CHST2 | c.392C>G p.A131G | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV58886289; called by muse, mutect2, varscan2
- CKAP4 | c.1222G>T p.G408* | Nonsense Mutation (SNP) | VAF 50/101 reads (50%) | catalogued as COSV65172983; called by muse, mutect2, varscan2
- CLCA2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs1464824854, COSV65288031; called by muse, mutect2, varscan2
- CLPB | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 62/145 reads (43%) | catalogued as COSV53631444; called by muse, mutect2, varscan2
- CLRN2 | c.26G>T p.W9L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55551231; called by muse, mutect2, varscan2
- CNPPD1 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as rs995949361, COSV55406024, COSV55408654; called by muse, mutect2, varscan2
- CNTNAP5 | c.2600C>T p.S867F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV70482922; called by muse, mutect2, varscan2
- COL11A1 | c.4025G>T p.G1342V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100614507; called by muse, mutect2, varscan2
- COL24A1 | c.3516G>A p.R1172= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as COSV65309876; called by muse, mutect2
- COL25A1 | c.85C>G p.R29G | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV67653757, COSV67654119; called by muse, mutect2, varscan2
- COL27A1 | c.3181G>T p.A1061S | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV61928747; called by muse, mutect2, varscan2
- COL2A1 | c.4232T>C p.L1411P | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV100475179; called by muse, mutect2, varscan2
- COL3A1 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as rs759147777, COSV58593150, COSV58595814; called by muse, mutect2, varscan2
- COL3A1 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as CD942091, COSV58593162; called by muse, mutect2, varscan2
- COL4A1 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65428706; called by muse, mutect2, varscan2
- COL4A3 | c.3967A>T p.N1323Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV67417517; called by muse, mutect2, varscan2
- COL5A1 | c.3741G>T p.Q1247H | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV65672119; called by muse, mutect2, varscan2
- COL5A2 | c.151A>T p.R51W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV66411860; called by muse, mutect2, varscan2
- COL6A3 | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1243322338, COSV55098910; called by muse, mutect2, varscan2
- COPA | c.1013A>G p.D338G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV54106083; called by muse, mutect2, varscan2
- COX5A | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs774638701, COSV59279449; called by muse, mutect2, varscan2
- CPA3 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56046187; called by muse, mutect2, varscan2
- CPA4 | c.1101C>G p.I367M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV55984239, COSV99745132; called by muse, mutect2, varscan2
- CPA5 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV62570220; called by muse, mutect2, varscan2
- CPB2 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV51676021, COSV51676917; called by muse, mutect2
- CPD | c.2044G>C p.D682H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56714453; called by muse, mutect2, varscan2
- CPS1 | c.2716A>T p.R906W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV99241562; called by muse, mutect2, varscan2
- CPS1 | c.2717G>T p.R906M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs749952015, COSV99241572; called by muse, mutect2, varscan2
- CPXM2 | c.2036G>T p.W679L | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99580689; called by muse, mutect2, varscan2
- CPXM2 | c.2035T>C p.W679R | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99580693; called by muse, varscan2
- CR2 | c.2875C>A p.H959N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV65508698; called by muse, mutect2, varscan2
- CRB1 | c.1544A>T p.Q515L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV66331887; called by muse, mutect2, varscan2
- CRYBG3 | c.7060G>T p.G2354W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51714168; called by muse, mutect2, varscan2
- CSMD2 | c.9778G>A p.E3260K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1440418847, COSV53882961; called by muse, mutect2, varscan2
- CSMD3 | c.10334C>A p.A3445E (on ENST00000297405 / NM_001363185.1; = p.A3276E on NM_052900.3) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV52248662, COSV99850884; called by muse, mutect2, varscan2
- CSMD3 | c.7073C>A p.A2358D (on ENST00000297405 / NM_001363185.1; = p.A2254D on NM_052900.3) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV52091847; called by muse, mutect2
- CSMD3 | c.4958C>A p.P1653Q (on ENST00000297405 / NM_001363185.1; = p.P1549Q on NM_052900.3) | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV52248698; called by muse, mutect2, varscan2
- CSMD3 | c.4124G>T p.S1375I (on ENST00000297405 / NM_001363185.1; = p.S1271I on NM_052900.3) | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV52248716; called by muse, mutect2, varscan2
- CTNND2 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 200/257 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58907263; called by muse, mutect2, varscan2
- CXCR1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs140728083; called by muse, mutect2, varscan2
- CYP26C1 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53653344; called by muse, mutect2, varscan2
- DBNDD1 | c.412G>A p.D138N (on ENST00000002501 / NM_001042610.3; = p.D158N on NM_024043.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs774519207, COSV50022383; called by muse, mutect2, varscan2
- DCHS1 | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV55039172; called by muse, mutect2, varscan2
- DCN | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV50008141; called by muse, mutect2, varscan2
- DCST1 | c.1612C>A p.P538T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs780909658, COSV55057242, COSV55061157; called by muse, mutect2, varscan2
- DDHD1 | c.1336G>T p.D446Y (on ENST00000323669; = p.D643Y on NM_030637.3) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60357860, COSV60360826; called by muse, mutect2, varscan2
- DDN | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as rs1319391392, COSV70404923; called by muse, mutect2, varscan2
- DECR2 | c.726G>C p.K242N | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.676); catalogued as COSV54795474; called by muse, mutect2, varscan2
- DENND1B | c.2009A>T p.K670M | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV54153583; called by muse, mutect2, varscan2
- DHX9 | c.1915G>T p.A639S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.348); catalogued as COSV62360859; called by muse, mutect2, varscan2
- DIDO1 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.182); catalogued as COSV99824355; called by muse, mutect2, varscan2
- DIS3 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.357); catalogued as rs373230191; called by muse, mutect2
- DLD | c.614G>C p.G205A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52738902; called by muse, mutect2
- DLG2 | c.2166T>A p.D722E | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV54665764; called by muse, mutect2, varscan2
- DLGAP1 | c.2456G>T p.R819L | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV59801271, COSV59819852; called by muse, mutect2, varscan2
- DMD | c.7225G>T p.E2409* | Nonsense Mutation (SNP) | VAF 61/75 reads (81%) | catalogued as COSV58930579, COSV58945816; called by muse, mutect2, varscan2
- DNAAF5 | c.1738C>T p.H580Y | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs775095718, COSV52419199; called by muse, mutect2, varscan2
- DNAH3 | c.8297C>T p.A2766V | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.982); catalogued as rs949552481, COSV54536225; called by muse, mutect2, varscan2
- DNAH3 | c.3517A>C p.R1173= | Splice Region (SNP) | VAF 21/49 reads (43%) | catalogued as COSV54536238; called by muse, mutect2, varscan2
- DNAJB4 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV66131926; called by muse, mutect2, varscan2
- DNAJB5 | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56626604; called by muse, mutect2, varscan2
- DNASE1L3 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59156819; called by muse, mutect2, varscan2
- DNER | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59171303; called by muse, mutect2, varscan2
- DOCK2 | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV56972851; called by muse, mutect2, varscan2
- DOP1B | c.5105G>A p.R1702H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs779189283, COSV67693011; called by muse, mutect2, varscan2
- DPH6 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56616830; called by muse, mutect2, varscan2
- DPP6 | c.982C>A p.L328I (on ENST00000377770 / NM_001364500.2; = p.L266I on NM_001936.5) | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.049); catalogued as COSV59630676; called by muse, mutect2, varscan2
- DPPA2 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV72118212; called by muse, mutect2, varscan2
- DRC1 | c.1728C>A p.S576R | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV55510493; called by muse, mutect2, varscan2
- DRC7 | c.1205T>C p.L402P | Missense Mutation (SNP) | VAF 66/96 reads (69%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.571); catalogued as COSV61056621; called by muse, mutect2, varscan2
- DRC7 | c.1924A>T p.S642C | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV61056632; called by muse, mutect2, varscan2
- DSC1 | c.398A>G p.K133R | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs761035986, COSV57148617; called by muse, mutect2, varscan2
- DSC3 | c.1743T>A p.Y581* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV64574115; called by muse, mutect2, varscan2
- DSCAM | c.5948C>T p.A1983V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV68031613; called by muse, mutect2, varscan2
- DSEL | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59493227; called by muse, mutect2, varscan2
- DSG2 | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55201005; called by muse, mutect2, varscan2
- DST | c.18117G>T p.E6039D (on ENST00000361203 / NM_001374722.1; = p.E3736D on NM_015548.5) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); catalogued as COSV55027475; called by muse, mutect2, varscan2
- DUSP29 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.575); catalogued as COSV58301116; called by muse, mutect2, varscan2
- DYTN | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs376587365; called by muse, mutect2, varscan2
- EIF3F | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.335); catalogued as rs143020927, COSV59142737; called by muse, mutect2, varscan2
- EIF4G3 | c.2085+1G>T p.X695_splice | Splice Site (SNP) | VAF 59/87 reads (68%) | catalogued as COSV51688018; called by muse, mutect2, varscan2
- ELAPOR1 | c.1994C>G p.P665R | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV64040835; called by muse, mutect2, varscan2
- ENDOU | c.861C>A p.F287L (on ENST00000422538 / NM_001172439.2; = p.F246L on NM_006025.4) | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57464763, COSV57465535; called by muse, mutect2, varscan2
- ENGASE | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100285622; called by muse, mutect2, varscan2
- ENO1 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52304742; called by muse, mutect2, varscan2
- ENPEP | c.1963C>A p.R655S | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54454170; called by muse, mutect2, varscan2
- ENPP1 | c.557-1G>A p.X186_splice | Splice Site (SNP) | VAF 13/24 reads (54%) | catalogued as rs1320905778, COSV62934337; called by muse, mutect2, varscan2
- ENPP2 | c.579G>T p.R193S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV50023988; called by muse, mutect2, varscan2
- EPB41L2 | c.1639G>T p.V547F | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV61357346; called by muse, varscan2
- EPG5 | c.5116A>T p.I1706F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV56352850; called by muse, mutect2, varscan2
- EPHB1 | c.2013C>G p.I671M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67666019; called by muse, mutect2, varscan2
- EPRS1 | c.4018C>T p.R1340C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs143796513; called by muse, mutect2, varscan2
- EPX | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56597991; called by muse, mutect2, varscan2
- ERBIN | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52320821, COSV52322051; called by muse, mutect2, varscan2
- ESYT2 | c.620C>A p.P207H (on ENST00000613624; = p.P131H on NM_020728.3) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99275879; called by muse, mutect2, varscan2
- ETV3L | c.695T>A p.F232Y | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV71901157; called by muse, mutect2, varscan2
- EVC2 | c.1414A>T p.R472* | Nonsense Mutation (SNP) | VAF 149/208 reads (72%) | catalogued as COSV60397995; called by muse, mutect2, varscan2
- EXOC8 | c.776G>T p.S259I | Missense Mutation (SNP) | VAF 54/73 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV50478822; called by muse, mutect2, varscan2
- EYS | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as rs528733427, CM121447, COSV100676849, COSV60982705, COSV60993480; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F13B | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66374860; called by muse, mutect2, varscan2
- FAAH2 | c.373G>T p.G125W | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66510045; called by muse, mutect2, varscan2
- FAM117A | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV53603684; called by muse, mutect2, varscan2
- FAM133B | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70075916; called by muse, mutect2, varscan2
- FAM135B | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50532042, COSV50538748; called by muse, mutect2
- FAM171A1 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV65317780; called by muse, mutect2, varscan2
- FAM171B | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV59006074; called by muse, mutect2, varscan2
- FAM3C | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV63436076; called by muse, mutect2, varscan2
- FAM47C | c.1595C>A p.S532Y | Missense Mutation (SNP) | VAF 158/187 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782317036, COSV63728767; called by muse, mutect2, varscan2
- FAM71C | c.92A>C p.Q31P | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60943845; called by muse, mutect2
- FAM98A | c.1307G>C p.G436A | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.345); catalogued as COSV53211111; called by muse, mutect2, varscan2
- FAM9B | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59120007; called by muse, varscan2
- FANCG | c.1621G>T p.V541L | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV62721400; called by muse, mutect2, varscan2
- FANCL | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as rs754028115, COSV52076153; called by muse, mutect2, varscan2
- FCHSD2 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.36); catalogued as COSV60812493; called by muse, varscan2
- FCRL5 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.842); catalogued as rs1171737723, COSV62517446; called by muse, mutect2, varscan2
- FGD6 | c.3418G>C p.V1140L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544538081, COSV59695140; called by muse, mutect2, varscan2
- FGFR4 | c.122A>T p.Q41L | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52806689; called by muse, mutect2, varscan2
- FLG | c.6485G>C p.G2162A | Missense Mutation (SNP) | VAF 248/635 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs748258789, COSV64244932; called by muse, mutect2, varscan2
- FMO1 | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.559); catalogued as COSV61446808; called by muse, varscan2
- FNDC1 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs199545417, COSV51938712, COSV99797830; called by muse, mutect2, varscan2
- FRMPD2 | c.2090G>A p.G697D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs755068594, COSV59720921; called by muse, mutect2, varscan2
- FRMPD4 | c.1100C>G p.P367R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66219267; called by muse, mutect2, varscan2
- FZD10 | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.892); catalogued as COSV57474645; called by muse, mutect2, varscan2
- GABRA2 | c.704-1G>T p.X235_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | catalogued as COSV62915943; called by muse, mutect2
- GABRA3 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64802378; called by muse, varscan2
- GABRB2 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.98); catalogued as COSV50926762; called by muse, mutect2, varscan2
- GAK | c.1372A>T p.R458W | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58507014; called by muse, mutect2, varscan2
- GANAB | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV60466789, COSV60467928; called by muse, mutect2, varscan2
- GATA3 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV60520760, COSV60521164; called by muse, mutect2, varscan2
- GDF10 | c.581C>A p.A194E | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as rs370459077; called by muse, mutect2, varscan2
- GDPD3 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221802274, COSV53775176; called by muse, mutect2, varscan2
- GEN1 | c.2674G>T p.D892Y | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58057669; called by muse, mutect2, varscan2
- GET1 | c.362G>C p.W121S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV61555138; called by muse, mutect2, varscan2
- GFM1 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV51834347; called by muse, mutect2, varscan2
- GFRAL | c.739C>A p.R247S | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV61233232; called by muse, mutect2, varscan2
- GHR | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 51/54 reads (94%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV50120671; called by muse, mutect2, varscan2
- GLDC | c.862-1G>A p.X288_splice | Splice Site (SNP) | VAF 19/40 reads (48%) | catalogued as COSV58682661; called by muse, mutect2, varscan2
- GLRA1 | c.250A>G p.M84V | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV51014929; called by muse, mutect2, varscan2
- GLT1D1 | c.166T>A p.C56S | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV55884716; called by muse, mutect2, varscan2
- GMIP | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 119/158 reads (75%) | SIFT tolerated (0.23); PolyPhen benign (0.134); catalogued as rs758071599, COSV52558277; called by muse, mutect2, varscan2
- GMPS | c.143T>A p.L48Q | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as COSV55810697; called by muse, mutect2, varscan2
- GMPS | c.321G>T p.M107I | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV55810703; called by muse, mutect2, varscan2
- GOLGA3 | c.3722A>T p.Q1241L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV52637449; called by muse, mutect2, varscan2
- GOLGA6A | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV51804549, COSV51806200; called by muse, mutect2, varscan2
- GP5 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1238486512, COSV59879327; called by muse, mutect2, varscan2
- GPD2 | c.1687G>T p.V563F | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV60094869; called by muse, mutect2, varscan2
- GPR139 | c.877del p.R293Afs*29 | Frame Shift Del (DEL) | VAF 54/137 reads (39%) | catalogued as COSV58501834; called by mutect2, pindel, varscan2
- GPR158 | c.3291G>C p.E1097D | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV66270688, COSV66276660; called by muse, mutect2, varscan2
- GPR26 | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV52934815, COSV52935188; called by muse, mutect2, varscan2
- GPRC5B | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56027578; called by muse, mutect2, varscan2
- GPRIN2 | c.843G>T p.R281S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.124); catalogued as rs71265691, COSV65401739; called by muse, mutect2, varscan2
- GREB1 | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52180182, COSV52191917; called by muse, mutect2, varscan2
- GRHPR | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58944179; called by muse, mutect2, varscan2
- GRIA4 | c.340C>A p.H114N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV56908639, COSV56918104; called by muse, mutect2, varscan2
- GRID2 | c.2145C>A p.S715R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV56233355; called by muse, mutect2, varscan2
- GRM7 | c.686G>C p.S229T | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV63155504; called by muse, mutect2, varscan2
- GSG1L | c.842G>C p.R281T (on ENST00000447459 / NM_001109763.2; = p.R126T on NM_144675.2) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV66580474; called by muse, mutect2, varscan2
- HCN1 | c.1522G>T p.V508L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs180790607, COSV57495369, COSV57501466; called by muse, mutect2, varscan2
- HDX | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52980157; called by muse, mutect2, varscan2
- HECTD4 | c.3964G>C p.V1322L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as COSV61180605, COSV61181984; called by muse, mutect2
- HEPACAM2 | c.277G>C p.E93Q (on ENST00000394468 / NM_001039372.4; = p.E81Q on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.815); catalogued as COSV59062033; called by muse, mutect2, varscan2
- HEPHL1 | c.955del p.R319Gfs*17 | Frame Shift Del (DEL) | VAF 34/160 reads (21%) | catalogued as COSV59889184; called by mutect2, pindel, varscan2
- HERC1 | c.4901C>A p.A1634E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV71249031; called by muse, mutect2
- HERC2 | c.1191G>T p.M397I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV55337163; called by muse, mutect2, varscan2
- HIPK2 | c.2822G>T p.R941L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.187); catalogued as rs550978102, COSV61226047, COSV61230529; called by muse, mutect2, varscan2
- HIVEP2 | c.391_392insG p.P131Rfs*6 | Frame Shift Ins (INS) | VAF 49/93 reads (53%) | catalogued as COSV99171405; called by mutect2, pindel, varscan2
- HMCN1 | c.10316C>A p.S3439* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as COSV54919551, COSV54934899; called by muse, mutect2, varscan2
- HMG20A | c.908-1G>T p.X303_splice | Splice Site (SNP) | VAF 10/55 reads (18%) | catalogued as COSV60313439; called by muse, mutect2, varscan2
- HOXD10 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV50901273; called by muse, mutect2, varscan2
- HS3ST2 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54465388; called by muse, mutect2, varscan2
- HSD17B6 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs752559848, COSV59108325; called by muse, mutect2, varscan2
- HSD3B7 | c.523G>T p.G175W | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370554987, COSV52681149; called by muse, mutect2, varscan2
- HSPA12B | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as COSV53924783; called by mutect2, varscan2
- IDE | c.2117-2A>T p.X706_splice | Splice Site (SNP) | VAF 27/110 reads (25%) | catalogued as COSV56425432; called by muse, mutect2, varscan2
- IFIT5 | c.399C>G p.Y133* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV65655751; called by muse, mutect2, varscan2
- IGDCC4 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61538229; called by muse, mutect2, varscan2
- IKZF5 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64397809; called by muse, mutect2, varscan2
- IL18R1 | c.1289A>T p.H430L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV52125981; called by muse, mutect2, varscan2
- IL5 | c.83C>A p.A28E | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.6); PolyPhen benign (0.043); catalogued as COSV51504776; called by muse, mutect2, varscan2
- INPP5B | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as COSV65958466; called by muse, mutect2, varscan2
- IQCE | c.96G>T p.R32S | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV58077109, COSV58080131; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.4C>A p.R2S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV67334353, COSV67334530; called by muse, mutect2, varscan2
- ITGA2B | c.2006C>G p.A669G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV52233706; called by muse, mutect2, varscan2
- ITGB7 | c.1224C>A p.Y408* | Nonsense Mutation (SNP) | VAF 46/104 reads (44%) | catalogued as COSV57238424, COSV57239495; called by muse, mutect2, varscan2
- ITIH6 | c.2665A>G p.R889G | Missense Mutation (SNP) | VAF 46/58 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV54491445; called by muse, mutect2, varscan2
- IWS1 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as COSV54870110; called by muse, mutect2, varscan2
- KALRN | c.1616G>T p.C539F | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV53773186; called by muse, mutect2, varscan2
- KALRN | c.8212C>T p.P2738S (on ENST00000360013 / NM_001024660.4; = p.P1041S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52260803; called by muse, mutect2, varscan2
- KAT2A | c.2414G>A p.R805H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1555665181, COSV52425537; called by muse, mutect2, varscan2
- KCNA4 | c.1414A>T p.R472* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV60254119; called by muse, mutect2, varscan2
- KCNB2 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 23/293 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs764013780, COSV73049004; called by muse, mutect2
- KCNG1 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs1273123579, COSV100857014, COSV65369026; called by muse, mutect2, varscan2
- KCNH7 | c.2360G>T p.R787I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59805092; called by muse, mutect2, varscan2
- KCNH7 | c.785G>C p.R262T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.138); catalogued as COSV100036890, COSV59805107; called by muse, mutect2, varscan2
- KCNJ3 | c.581T>A p.L194H | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54540158; called by muse, mutect2, varscan2
- KCNJ3 | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.196); catalogued as COSV54540166, COSV99716248; called by muse, mutect2, varscan2
- KCNK9 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.029); catalogued as COSV57285290; called by muse, mutect2
- KCNQ2 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60436765; called by muse, mutect2, varscan2
- KCTD8 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV63589572; called by muse, mutect2, varscan2
- KEL | c.1496A>T p.Q499L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV62336473; called by muse, mutect2, varscan2
- KEL | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV62336484; called by muse, mutect2, varscan2
- KIAA1210 | c.4513T>A p.S1505T | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV68178571; called by muse, mutect2, varscan2
- KIAA1755 | c.1085C>A p.T362N | Missense Mutation (SNP) | VAF 100/199 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV54078615; called by muse, mutect2, varscan2
- KIF17 | c.1484T>A p.V495E | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV56120421; called by muse, mutect2, varscan2
- KIRREL1 | c.1523T>A p.L508Q | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV63289444; called by muse, mutect2, varscan2
- KLB | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57303272; called by muse, mutect2, varscan2
- KLHL26 | c.1528A>G p.I510V | Missense Mutation (SNP) | VAF 52/59 reads (88%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV56318532; called by muse, mutect2, varscan2
- KLHL36 | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.591); catalogued as COSV50721078; called by muse, mutect2, varscan2
- KNG1 | c.241G>T p.G81W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53979521; called by muse, mutect2, varscan2
- KRT31 | c.599C>A p.T200N | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as COSV52436749; called by muse, mutect2, varscan2
- KRT6C | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV52878914; called by muse, mutect2, varscan2
- KRT7 | c.1014G>T p.E338D | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV59332016; called by muse, mutect2, varscan2
- KRT72 | c.1282C>A p.R428S | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV53375363, COSV53375470; called by muse, mutect2, varscan2
- KRT72 | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53375375; called by muse, mutect2, varscan2
- KRT82 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs763665856, COSV57786007, COSV99233958; called by muse, mutect2, varscan2
- KRTAP26-1 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 63/87 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV62129072; called by muse, mutect2, varscan2
- LACTB2 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 51/446 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52568781; called by muse, mutect2, varscan2
- LAMA2 | c.557C>A p.T186N | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as COSV70351979; called by muse, mutect2, varscan2
- LAMB4 | c.3043C>A p.L1015I | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV52725008; called by muse, varscan2
- LAMB4 | c.3013C>A p.L1005I | Missense Mutation (SNP) | VAF 127/185 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.197); catalogued as COSV52725028; called by muse, varscan2
- LAMB4 | c.2611C>A p.L871I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.644); catalogued as COSV52725049; called by muse, mutect2, varscan2
- LBHD1 | c.870G>C p.*290Yext*1 (on ENST00000431002 / NM_001367940.1; = p.*264Yext*1 on NM_024099.3) | Nonstop Mutation (SNP) | VAF 33/68 reads (49%) | catalogued as rs1332473135, COSV63473268; called by muse, mutect2, varscan2
- LCLAT1 | c.503A>T p.Y168F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58375507; called by muse, mutect2, varscan2
- LDHAL6B | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55691275; called by muse, mutect2, varscan2
- LINGO1 | c.1284C>G p.D428E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV62437763; called by muse, varscan2
- LIPC | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs754538725, COSV54425218; called by muse, mutect2, varscan2
- LMBRD1 | c.395G>C p.S132T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV65298372; called by muse, varscan2
- LMX1A | c.869A>T p.Y290F | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV54224581; called by muse, varscan2
- LNPK | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV55825240; called by muse, mutect2, varscan2
- LRATD1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54473601; called by muse, mutect2, varscan2
- LRP1B | c.12116G>A p.G4039E | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1408793616, COSV67216291, COSV67249502; called by muse, mutect2, varscan2
- LRP1B | c.10527C>A p.N3509K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.265); catalogued as COSV67249505; called by muse, mutect2, varscan2
- LRP1B | c.9271G>T p.A3091S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV101262149, COSV67201387, COSV67249506; called by muse, mutect2, varscan2
- LRP1B | c.4357C>A p.L1453I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.125); catalogued as COSV67249513; called by muse, mutect2, varscan2
- LRP2 | c.13111A>G p.I4371V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs762279829, COSV55563677; called by muse, mutect2, varscan2
- LRP2 | c.9980C>A p.A3327D | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV55563691; called by muse, mutect2, varscan2
- LRRC66 | c.1489G>C p.A497P | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58635325; called by muse, mutect2, varscan2
- LRRK2 | c.2239C>T p.Q747* | Nonsense Mutation (SNP) | VAF 118/129 reads (91%) | catalogued as COSV54161797; called by muse, mutect2, varscan2
- LRRTM3 | c.279C>A p.D93E | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63668791; called by muse, mutect2, varscan2
- LRTM1 | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 12/13 reads (92%) | catalogued as COSV55560285; called by muse, mutect2, varscan2
- LSAMP | c.906C>A p.S302R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61301976; called by muse, mutect2, varscan2
- LTO1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 26/133 reads (20%) | catalogued as COSV54163210; called by muse, mutect2, varscan2
- LYAR | c.788A>T p.E263V | Missense Mutation (SNP) | VAF 96/251 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV58643441; called by muse, mutect2, varscan2
- LYZL4 | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 32/39 reads (82%) | catalogued as COSV55103835, COSV55104652; called by muse, mutect2, varscan2
- MAB21L2 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV58262701; called by muse, mutect2, varscan2
- MAGEB6 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV66872576, COSV66872641; called by muse, mutect2, varscan2
- MAGEC1 | c.1227G>C p.Q409H | Missense Mutation (SNP) | VAF 135/251 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53577237; called by muse, mutect2, varscan2
- MAGI2 | c.2837C>A p.S946Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV62680661, COSV62695752; called by muse, mutect2, varscan2
- MAP3K19 | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1559152842, COSV100207884; called by muse, mutect2, varscan2
- MAP3K9 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV67122188; called by muse, mutect2, varscan2
- MARCHF11 | c.980C>A p.A327D | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV100197214; called by muse, mutect2, varscan2
- MARCHF5 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV62770248; called by muse, mutect2, varscan2
- MARF1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV60026267; called by muse, mutect2, varscan2
- MATN4 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | PolyPhen benign (0.05); catalogued as rs1378466097, COSV59214952; called by muse, mutect2, varscan2
- MB21D2 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.84); catalogued as COSV66664775; called by muse, mutect2, varscan2
- MBOAT2 | c.969G>C p.L323F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60010549; called by muse, mutect2, varscan2
- MCC | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV68728786; called by muse, mutect2, varscan2
- MCTP1 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.43); PolyPhen benign (0.134); catalogued as COSV56510455, COSV56525148; called by muse, mutect2, varscan2
- MDGA1 | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51799173; called by muse, mutect2, varscan2
- MDM2 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50700965; called by muse, mutect2, varscan2
- MEGF10 | c.2621C>A p.A874E | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV57253161; called by muse, mutect2, varscan2
- METAP1D | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.038); catalogued as COSV59931213; called by muse, mutect2, varscan2
- METTL16 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as rs1422441034, COSV54014182; called by muse, mutect2, varscan2
- MGA | c.8204A>G p.N2735S (on ENST00000219905 / NM_001164273.1; = p.N2526S on NM_001080541.2) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1420692421, COSV54958823; called by muse, mutect2
- MGAM | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.318); catalogued as COSV72075122; called by muse, mutect2, varscan2
- MICAL3 | c.4634C>A p.T1545K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV71588776; called by muse, mutect2, varscan2
- MORC1 | c.2324+1G>T p.X775_splice | Splice Site (SNP) | VAF 11/54 reads (20%) | catalogued as COSV51725462; called by muse, varscan2
- MORC1 | c.1183G>C p.A395P | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs114679116, COSV51725480; called by muse, mutect2, varscan2
- MRGPRD | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58423631; called by muse, mutect2, varscan2
- MROH2B | c.1238C>A p.P413Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV101271002, COSV68186948; called by muse, mutect2
- MROH7 | c.1035C>A p.F345L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.013); catalogued as COSV59875155; called by muse, mutect2, varscan2
- MRPS28 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 76/103 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52563645; called by muse, mutect2, varscan2
- MTERF1 | c.39A>T p.K13N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.265); catalogued as COSV61098744; called by muse, mutect2, varscan2
- MTNR1A | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV56157025; called by muse, mutect2, varscan2
- MTRR | c.506G>T p.W169L (on ENST00000264668; = p.W142L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52945412; called by muse, mutect2, varscan2
- MUC16 | c.40157G>T p.G13386V | Missense Mutation (SNP) | VAF 48/60 reads (80%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66691443; called by muse, mutect2, varscan2
- MUC16 | c.9172G>T p.G3058W | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV67479451; called by muse, varscan2
- MUC16 | c.7265C>A p.T2422K | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV67479716; called by muse, mutect2, varscan2
- MUC16 | c.2966C>A p.A989D | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV67479721; called by muse, varscan2
- MUC17 | c.119G>C p.G40A | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV60296082; called by muse, mutect2, varscan2
- MUC17 | c.11573C>T p.P3858L | Missense Mutation (SNP) | VAF 59/100 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV60296090; called by muse, mutect2, varscan2
- MUC5B | c.5758A>C p.T1920P | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV71594201; called by muse, mutect2, varscan2
- MYBPC1 | c.2162C>A p.P721H (on ENST00000550270 / NM_206820.2; = p.P746H on NM_002465.4) | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62255411; called by muse, mutect2, varscan2
- MYEF2 | c.1138G>T p.G380* | Nonsense Mutation (SNP) | VAF 47/95 reads (49%) | catalogued as COSV51050082, COSV51052078; called by muse, mutect2, varscan2
- MYH15 | c.1804A>G p.I602V | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.508); catalogued as COSV56315071; called by muse, mutect2, varscan2
- MYH2 | c.3576A>T p.E1192D | Missense Mutation (SNP) | VAF 100/164 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55443270; called by muse, mutect2, varscan2
- MYH4 | c.2524C>A p.P842T | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV55112646; called by muse, mutect2, varscan2
- MYH7 | c.4058C>A p.A1353D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62521486; called by muse, mutect2, varscan2
- MYO15A | c.1589C>G p.P530R | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.925); catalogued as COSV52760987; called by muse, mutect2, varscan2
- MYO18B | c.7123C>A p.L2375M | Missense Mutation (SNP) | VAF 65/89 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV59141528; called by muse, mutect2, varscan2
- MYO3B | c.1006G>T p.V336L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV58710016; called by muse, mutect2, varscan2
- MYOC | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.306); catalogued as COSV50676354; called by muse, mutect2, varscan2
- MYOF | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV63707595; called by muse, mutect2, varscan2
- MYOZ1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63772310; called by muse, mutect2, varscan2
- MYPN | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV62736111; called by muse, mutect2, varscan2
- NARS2 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV55253769; called by muse, mutect2, varscan2
- NAV2 | c.274A>T p.T92S | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100585344, COSV62328428; called by muse, mutect2, varscan2
- NAV3 | c.2749C>A p.P917T | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV99885955; called by muse, mutect2, varscan2
- NAV3 | c.3992C>A p.S1331Y | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57096731, COSV99896922; called by muse, mutect2, varscan2
- NCOA2 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71763363, COSV71764438; called by muse, mutect2, varscan2
- NEK11 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV63582073; called by muse, mutect2, varscan2
- NEK8 | c.1184A>T p.H395L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV52046890; called by muse, mutect2, varscan2
- NES | c.3917G>T p.R1306M | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV63961870; called by muse, mutect2, varscan2
- NEXMIF | c.2742T>G p.S914R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV50057924; called by muse, mutect2, varscan2
- NF1 | c.1657C>T p.H553Y | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62211513; called by muse, mutect2, varscan2
- NFATC3 | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60473157; called by muse, mutect2, varscan2
- NFE2 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV56456538; called by muse, mutect2, varscan2
- NIPAL3 | c.274del p.A92Pfs*19 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | catalogued as COSV50231793; called by pindel*, varscan2
- NLRP9 | c.2624A>C p.Q875P | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV60465839; called by muse, mutect2, varscan2
- NNT | c.2675A>G p.Y892C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1342376066, COSV52927364; called by muse, mutect2, varscan2
- NOL4 | c.1577C>A p.P526Q | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52353932; called by muse, mutect2, varscan2
- NPAP1 | c.187A>T p.S63C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61509030; called by muse, mutect2, varscan2
- NPAP1 | c.2817C>A p.S939R | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV61509037; called by muse, mutect2, varscan2
- NPAP1 | c.3098C>G p.S1033* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV61507685, COSV61509041; called by muse, mutect2, varscan2
- NPHS1 | c.3244G>T p.G1082W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as CM156491, COSV62289017, COSV62289242; called by muse, mutect2, varscan2
- NR0B1 | c.1387C>A p.L463M | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as COSV66764411; called by muse, mutect2, varscan2
- NRCAM | c.2873T>G p.L958W (on ENST00000379028 / NM_001371124.1; = p.L942W on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61042770; called by muse, mutect2
- NRCAM | c.289A>G p.M97V (on ENST00000379028 / NM_001371124.1; = p.M91V on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs150121000; called by muse, mutect2, varscan2
- NRG3 | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV64573882; called by muse, mutect2, varscan2
- NRXN1 | c.3220G>T p.G1074* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV58472838, COSV58489265; called by muse, mutect2
- NSD1 | c.5458G>A p.V1820M | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs752685166, COSV61773772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUDT22 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV54174691; called by muse, mutect2, varscan2
- NUMBL | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs762990433, COSV53284486; called by muse, varscan2
- NUP210 | c.1010A>G p.N337S | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.802); catalogued as COSV54409820; called by muse, mutect2, varscan2
- OR10G9 | c.794A>T p.D265V | Missense Mutation (SNP) | VAF 69/120 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as COSV66686514; called by muse, mutect2, varscan2
- OR10Q1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1369921729, COSV57469928; called by muse, mutect2, varscan2
- OR10S1 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101602483, COSV73342652, COSV73342905; called by muse, varscan2
- OR10S1 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV73342907; called by muse, varscan2
- OR11L1 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.463); catalogued as COSV63315046; called by muse, mutect2, varscan2
- OR2D2 | c.26T>G p.V9G | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV55057679; called by muse, mutect2, varscan2
- OR2G6 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV58575103, COSV58575269; called by muse, mutect2, varscan2
- OR2T10 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV57897532; called by muse, mutect2, varscan2
- OR2T34 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 104/177 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779030084, COSV60901135, COSV60902204; called by muse, mutect2, varscan2
- OR4A5 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.288); catalogued as rs747204814, COSV60523509; called by muse, varscan2
- OR4C13 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 127/246 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV73648828; called by muse, mutect2, varscan2
- OR4K13 | c.467C>A p.S156* | Nonsense Mutation (SNP) | VAF 33/86 reads (38%) | catalogued as COSV59858866, COSV59860197; called by muse, mutect2, varscan2
- OR4L1 | c.841T>A p.L281I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV100235526; called by muse, varscan2
- OR4L1 | c.842T>C p.L281S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs975818140, COSV100235528; called by muse, varscan2
- OR4L1 | c.843A>T p.L281F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV100235529; called by muse, varscan2
- OR4N2 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV60053178, COSV60053556; called by muse, mutect2, varscan2
- OR4N5 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61320999; called by muse, mutect2, varscan2
- OR51A2 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66748607; called by muse, mutect2, varscan2
- OR51D1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as COSV62914471, COSV62914925; called by muse, mutect2, varscan2
- OR52N2 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs746188141, COSV57676062, COSV57677371; called by muse, mutect2, varscan2
- OR5AP2 | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57258164; called by muse, mutect2, varscan2
- OR5D14 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV59457403; called by muse, mutect2, varscan2
- OR5D18 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs566365669, COSV61736850, COSV61737947; called by muse, mutect2, varscan2
- OR5D18 | c.871T>A p.Y291N | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61737180; called by muse, mutect2, varscan2
- OR5T1 | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 83/146 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1171319751, COSV57303813; called by muse, mutect2, varscan2
- OR6N1 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58649600; called by muse, mutect2, varscan2
- OR6N2 | c.280T>A p.F94I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); catalogued as COSV59412251; called by muse, mutect2, varscan2
- OR6Y1 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV56930308; called by muse, mutect2, varscan2
- OTC | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM981417, COSV50003172; called by muse, mutect2, varscan2
- OTOP2 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs1178898173, COSV58882787; called by muse, mutect2, varscan2
- OXCT2 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV59594261; called by muse, mutect2, varscan2
- PADI1 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV64938898; called by muse, mutect2, varscan2
- PADI1 | c.533A>G p.Q178R | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.338); catalogued as rs1451885591, COSV64938903; called by muse, mutect2, varscan2
- PAOX | c.578G>C p.C193S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.785); catalogued as COSV53373302; called by muse, mutect2, varscan2
- PAX5 | c.952C>A p.H318N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV63910084; called by muse, mutect2
- PAX5 | c.950C>A p.P317Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63910089; called by muse, mutect2
- PC | c.904-1G>T p.X302_splice | Splice Site (SNP) | VAF 43/103 reads (42%) | catalogued as COSV63081709; called by muse, mutect2, varscan2
- PCDH10 | c.1699C>G p.Q567E | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV52088403, COSV52089728; called by muse, mutect2, varscan2
- PCDHA13 | c.1787_1788del p.A596Gfs*14 | Frame Shift Del (DEL) | VAF 50/115 reads (43%) | catalogued as rs1554181152; called by pindel, varscan2
- PCDHA4 | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63540896, COSV63543934; called by muse, mutect2, varscan2
- PCDHB15 | c.2156C>A p.A719E | Missense Mutation (SNP) | VAF 121/174 reads (70%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as COSV50870072, COSV51242990; called by muse, mutect2, varscan2
- PCDHB3 | c.407A>T p.N136I | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV50584198, COSV50596947; called by muse, mutect2, varscan2
- PCDHGB5 | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs765946308, COSV53989359; called by muse, mutect2, varscan2
- PCK1 | c.1125G>T p.E375D | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60129827; called by muse, mutect2, varscan2
- PCLO | c.15181C>A p.Q5061K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV61625781, COSV61650318; called by muse, mutect2, varscan2
- PCLO | c.14416G>T p.V4806L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV61650328; called by muse, mutect2, varscan2
- PCSK9 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs372165281, COSV56161201; called by muse, mutect2, varscan2
- PDE10A | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63101781; called by muse, mutect2, varscan2
- PDE4DIP | c.5649G>A p.R1883= | Splice Region (SNP) | VAF 28/150 reads (19%) | catalogued as rs1282280555, COSV57711888; called by muse, mutect2, varscan2
- PDZRN3 | c.1999C>A p.P667T | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV55208243, COSV55216790; called by muse, varscan2
- PELO | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV50879077; called by muse, mutect2, varscan2
- PELP1 | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 60/72 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as rs760001532, COSV52590016; called by muse, mutect2, varscan2
- PHIP | c.2536A>T p.S846C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV51507331, COSV51507417; called by muse, varscan2
- PHLDB2 | c.3022A>T p.S1008C (on ENST00000393925 / NM_001134439.2; = p.S965C on NM_145753.2) | Missense Mutation (SNP) | VAF 73/123 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67313874; called by muse, mutect2, varscan2
- PHLDB3 | c.1907A>G p.E636G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); catalogued as COSV52670862; called by muse, mutect2, varscan2
- PHLPP1 | c.3245G>A p.C1082Y | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383828880, COSV53033428; called by muse, mutect2, varscan2
- PI15 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 29/310 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV52640149, COSV52643049; called by muse, mutect2
- PIK3CG | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs554272230, COSV63247299; called by muse, mutect2, varscan2
- PITX2 | c.943C>T p.R315W (on ENST00000354925 / NM_001204397.1; = p.R322W on NM_000325.6) | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1399453588, COSV100146222, COSV100146291, COSV60741638; called by muse, mutect2, varscan2
- PKHD1 | c.9124A>G p.I3042V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as COSV61886912; called by muse, mutect2, varscan2
- PKHD1 | c.6628G>C p.G2210R | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61886922; called by muse, mutect2, varscan2
- PLCH2 | c.3499C>G p.R1167G | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.02); catalogued as COSV53946518; called by muse, mutect2, varscan2
- PLD1 | c.821T>A p.F274Y | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV60571039; called by muse, mutect2, varscan2
- PLEKHA7 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV63048603; called by muse, mutect2, varscan2
- PLEKHG3 | c.1780G>T p.G594C (on ENST00000394691; = p.G650C on NM_001308147.2) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV55981714; called by muse, mutect2, varscan2
- PLOD2 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51466917, COSV51469596; called by muse, mutect2, varscan2
- PLPBP | c.506A>T p.N169I | Missense Mutation (SNP) | VAF 104/136 reads (76%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100065572, COSV60240002; called by muse, mutect2, varscan2
- PLPP4 | c.809C>A p.P270Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV64828804; called by muse, mutect2, varscan2
- PLXNA3 | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 59/74 reads (80%) | SIFT tolerated (0.39); PolyPhen benign (0.36); catalogued as COSV63754803; called by muse, mutect2, varscan2
- PLXNA4 | c.3588T>A p.D1196E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV58144161; called by muse, mutect2, varscan2
- PLXNA4 | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs867762798, COSV58102938; called by muse, mutect2, varscan2
- PLXNA4 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.609); catalogued as COSV100326985, COSV58144198; called by muse, mutect2, varscan2
- PM20D2 | c.982A>G p.M328V | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51531362; called by muse, mutect2, varscan2
- POLE | c.6101C>A p.S2034Y | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57685612; called by muse, mutect2, varscan2
- POM121 | c.2705C>G p.S902C (on ENST00000434423; = p.S637C on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV57515294, COSV57520027; called by muse, mutect2, varscan2
- POM121L12 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV68693537; called by muse, mutect2
- POP1 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | catalogued as COSV62893600; called by muse, mutect2
- POP1 | c.3031G>T p.A1011S | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); catalogued as COSV62893604; called by muse, mutect2, varscan2
- POU6F2 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.096); catalogued as rs367834526; called by muse, mutect2, varscan2
- PPM1E | c.1285T>C p.Y429H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57577091; called by muse, mutect2, varscan2
- PPP1R3A | c.1591A>G p.R531G | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52887504; called by muse, mutect2
- PRAC1 | c.9C>A p.C3* | Nonsense Mutation (SNP) | VAF 24/38 reads (63%) | catalogued as rs1446171363, COSV51704882, COSV99284881; called by muse, mutect2, varscan2
- PRAMEF4 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 144/482 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV52439852; called by muse, mutect2, varscan2
- PRDM10 | c.3190A>G p.M1064V | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV58803167; called by muse, mutect2, varscan2
- PRDM10 | c.728G>C p.G243A | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV58803173; called by muse, mutect2, varscan2
- PRKAA2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as COSV64805087; called by muse, mutect2, varscan2
- PRKDC | c.8207A>G p.Q2736R | Missense Mutation (SNP) | VAF 52/471 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV58058411; called by muse, mutect2, varscan2
- PRMT3 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58178919; called by muse, varscan2
- PRNP | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV65173721; called by muse, mutect2, varscan2
- PRRC2B | c.6649A>G p.I2217V | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV57645711; called by muse, mutect2, varscan2
- PSAP | c.866C>A p.S289Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.396); catalogued as COSV67550847; called by muse, mutect2, varscan2
- PSD4 | c.1797G>T p.E599D | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0.013); catalogued as COSV55528330; called by muse, mutect2, varscan2
- PSG4 | c.485T>C p.M162T | Missense Mutation (SNP) | VAF 115/163 reads (71%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1241793786, COSV54937978; called by muse, mutect2, varscan2
- PTCH2 | c.2404T>A p.S802T | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV64712282; called by muse, mutect2, varscan2
- PTPN14 | c.2911G>T p.V971L | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV65285892; called by muse, mutect2, varscan2
- PTPRF | c.5579G>T p.R1860L | Missense Mutation (SNP) | VAF 158/177 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63446871; called by muse, mutect2, varscan2
- PTPRM | c.2564T>A p.L855Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV59870744; called by muse, mutect2, varscan2
- PZP | c.3029C>T p.A1010V | Missense Mutation (SNP) | VAF 76/92 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54365238; called by muse, mutect2, varscan2
- R3HDML | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53836985; called by muse, mutect2, varscan2
- RAB19 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.07); catalogued as rs745326291, COSV52045525; called by muse, mutect2, varscan2
- RAD51AP1 | c.559G>T p.G187C (on ENST00000228843 / NM_001130862.2; = p.G170C on NM_006479.5) | Missense Mutation (SNP) | VAF 61/70 reads (87%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1193875309, COSV57411084; called by muse, mutect2, varscan2
- RAD51AP1 | c.655G>A p.D219N (on ENST00000228843 / NM_001130862.2; = p.D202N on NM_006479.5) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs758927962, COSV57411100; called by muse, mutect2, varscan2
- RANBP2 | c.8057G>T p.G2686V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51700191, COSV51704573; called by muse, varscan2
- RAPGEF4 | c.1035G>T p.E345D | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.225); catalogued as COSV51403816; called by muse, mutect2, varscan2
- RASAL2 | c.2644G>C p.A882P | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.828); catalogued as COSV62718158; called by muse, mutect2, varscan2
- RASGRP2 | c.1555-1G>T p.X519_splice | Splice Site (SNP) | VAF 20/80 reads (25%) | catalogued as COSV62450195; called by muse, mutect2, varscan2
- RASGRP2 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV62450202; called by muse, mutect2, varscan2
- RASSF2 | c.743A>C p.Q248P | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101040543; called by muse, mutect2, varscan2
- RBM24 | c.499G>A p.A167T (on ENST00000379052 / NM_001143942.2; = p.A122T on NM_153020.2) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.971); catalogued as COSV59004383, COSV59005902; called by muse, mutect2, varscan2
- RBM8A | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57162981; called by muse, mutect2, varscan2
- RBMS1 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 130/258 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62355264; called by muse, mutect2, varscan2
- RBMS1 | c.304T>C p.C102R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62355273; called by muse, mutect2
- RD3 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV65362598; called by muse, mutect2, varscan2
- RELN | c.2863A>C p.N955H | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59019639; called by muse, mutect2, varscan2
- RESF1 | c.4199G>A p.S1400N | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57023946; called by muse, mutect2, varscan2
- RFPL2 | c.293C>A p.A98E | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.873); catalogued as COSV50713595; called by muse, mutect2, varscan2
- RGPD1 | c.1264C>T p.H422Y (on ENST00000409776; = p.H430Y on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1200991572, COSV101233569; called by mutect2, varscan2
- RGS2 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as CM054099, COSV99343245; called by muse, mutect2, varscan2
- RGS7BP | c.767C>A p.S256* | Nonsense Mutation (SNP) | VAF 21/26 reads (81%) | catalogued as COSV61835911; called by muse, mutect2, varscan2
- RIC1 | c.253-1G>T p.X85_splice | Splice Site (SNP) | VAF 13/17 reads (76%) | catalogued as COSV52612409; called by muse, mutect2, varscan2
- RIMS2 | c.338C>A p.T113K | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68490857; called by muse, mutect2, varscan2
- RNF152 | c.323A>T p.K108M | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV57186799; called by muse, mutect2, varscan2
- RNF165 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53976041; called by muse, mutect2, varscan2
- ROBO2 | c.3599C>A p.P1200Q | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs376068100, COSV59925300; called by muse, mutect2, varscan2
- ROR1 | c.2315C>A p.S772Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV64290133; called by muse, mutect2, varscan2
- RPGRIP1 | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.038); catalogued as COSV52853411; called by muse, mutect2
- RTN4RL1 | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58676818; called by muse, mutect2
- RTP3 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56124130; called by muse, mutect2, varscan2
- RUBCN | c.2742G>T p.E914D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.103); catalogued as COSV56370058; called by muse, varscan2
- RUNX1T1 | c.1576T>A p.C526S (on ENST00000265814 / NM_001198628.1; = p.C499S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56155438; called by muse, mutect2, varscan2
- SAG | c.78G>T p.V26= | Splice Region (SNP) | VAF 4/9 reads (44%) | catalogued as COSV68591729; called by muse, mutect2, varscan2
- SALL3 | c.2804C>A p.T935N | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.674); catalogued as COSV73305974; called by muse, mutect2, varscan2
- SBNO1 | c.2882T>G p.V961G (on ENST00000420886; = p.V960G on NM_018183.5) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57343755; called by muse, mutect2, varscan2
- SCAPER | c.1814G>T p.R605L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57746778; called by muse, mutect2, varscan2
- SCCPDH | c.197C>A p.P66Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV63618959; called by muse, mutect2
- SCLY | c.1132G>T p.G378C (on ENST00000651534; = p.G370C on NM_016510.7) | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV54542776; called by muse, mutect2, varscan2
- SCML2 | c.487-2A>G p.X163_splice | Splice Site (SNP) | VAF 36/53 reads (68%) | catalogued as COSV52623417; called by muse, mutect2, varscan2
- SCN1A | c.652T>A p.F218I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM095602, COSV57678898; called by muse, mutect2, varscan2
- SCN2A | c.3111T>A p.D1037E | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51848075, COSV51848708; called by muse, mutect2, varscan2
- SCN4A | c.215del p.P72Rfs*43 | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | catalogued as CM152298, COSV71128044; called by mutect2, pindel, varscan2
- SCN8A | c.3392C>A p.S1131Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV61987202; called by muse, mutect2, varscan2
- SEC24B | c.1792A>G p.T598A | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV54503115; called by muse, mutect2, varscan2
- SEMA4A | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV61773353; called by muse, mutect2, varscan2
- SEPTIN14 | c.55C>A p.Q19K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as COSV101193155; called by mutect2, varscan2
- SERPINA3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV67586664; called by muse, mutect2, varscan2
- SERPINA3 | c.199A>T p.K67* | Nonsense Mutation (SNP) | VAF 57/93 reads (61%) | catalogued as COSV67586669; called by muse, mutect2, varscan2
- SERPINB12 | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 188/239 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV54034203, COSV99501799; called by muse, mutect2, varscan2
- SERPINB2 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55093575; called by muse, mutect2, varscan2
- SETBP1 | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56329697; called by muse, mutect2, varscan2
- SGIP1 | c.2134G>T p.D712Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV52774084; called by muse, mutect2, varscan2
- SGK3 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61895717; called by muse, mutect2
- SIPA1L3 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.427); catalogued as COSV55919367; called by muse, mutect2, varscan2
- SLC12A5 | c.1966G>T p.E656* (on ENST00000454036 / NM_001134771.2; = p.E633* on NM_020708.5) | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV54797741; called by mutect2, varscan2
- SLC15A1 | c.1450G>T p.G484W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64732681, COSV64733385; called by muse, mutect2, varscan2
- SLC16A6 | c.1290C>A p.S430R | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59178366; called by muse, mutect2, varscan2
- SLC18A3 | c.423G>T p.L141F | Missense Mutation (SNP) | VAF 53/68 reads (78%) | SIFT tolerated (0.92); PolyPhen benign (0.048); catalogued as COSV60328897; called by muse, mutect2, varscan2
- SLC22A12 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60573186; called by muse, mutect2, varscan2
- SLC2A10 | c.1367G>T p.W456L | Missense Mutation (SNP) | VAF 77/118 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100826363, COSV63715464; called by muse, mutect2, varscan2
- SLC4A3 | c.1277+1G>T p.X426_splice | Splice Site (SNP) | VAF 29/46 reads (63%) | catalogued as COSV56095800; called by muse, mutect2, varscan2
- SLC5A4 | c.1672C>A p.R558S | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV56672278; called by muse, mutect2, varscan2
- SLC7A13 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.067); catalogued as rs1216718585, COSV52535862; called by muse, mutect2, varscan2
- SLC8A1 | c.2420C>A p.S807Y | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759611239, COSV60489119; called by muse, mutect2, varscan2
- SLC9A8 | c.1074T>A p.C358* | Nonsense Mutation (SNP) | VAF 26/139 reads (19%) | catalogued as COSV64289752; called by muse, mutect2, varscan2
- SMARCAL1 | c.1852-2A>T p.X618_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV61922309; called by muse, mutect2
- SMIM19 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.988); catalogued as rs757691968, COSV60604720; called by muse, mutect2, varscan2
- SORCS1 | c.1907T>A p.L636Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53886493; called by muse, mutect2, varscan2
- SP140 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.662); catalogued as COSV59452534; called by muse, mutect2, varscan2
- SP140 | c.2146T>C p.C716R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59452548; called by muse, mutect2, varscan2
- SPAG6 | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV57622107; called by muse, mutect2, varscan2
- SPAM1 | c.102G>T p.L34F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV56145945; called by muse, mutect2, varscan2
- SPATA31A1 | c.3679C>T p.R1227C | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as rs1468217021; called by muse, mutect2, varscan2
- SPEG | c.580G>T p.V194F | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100403016; called by muse, mutect2, varscan2
- SPHKAP | c.4157C>A p.S1386Y | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.726); catalogued as rs1270065207, COSV60887326; called by muse, mutect2, varscan2
- SPOCD1 | c.1425+1G>A p.X475_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | catalogued as rs565382616, COSV57096507; called by muse, mutect2, varscan2
- SPP1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.099); catalogued as COSV52952267; called by muse, mutect2, varscan2
- SPTA1 | c.5030G>T p.G1677V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV63756740, COSV63761228; called by muse, mutect2, varscan2
- SPTBN1 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV61690925; called by muse, mutect2, varscan2
- SPTBN1 | c.2937G>T p.E979D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as COSV61690934; called by muse, mutect2, varscan2
- SPTBN2 | c.5825C>T p.A1942V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs765483709, COSV59452878; called by muse, mutect2, varscan2
- ST18 | c.278-1G>C p.X93_splice | Splice Site (SNP) | VAF 24/33 reads (73%) | catalogued as COSV52501391; called by muse, mutect2, varscan2
- ST6GAL2 | c.1483C>A p.L495M | Missense Mutation (SNP) | VAF 39/80 reads (49%) | PolyPhen benign (0.305); catalogued as COSV62417411; called by muse, mutect2, varscan2
- ST8SIA1 | c.492-1G>T p.X164_splice | Splice Site (SNP) | VAF 34/41 reads (83%) | catalogued as COSV53956755; called by muse, mutect2, varscan2
- STAB2 | c.6262C>A p.Q2088K | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV66342942; called by muse, mutect2, varscan2
- STAT1 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1398307167, COSV63116943; called by muse, mutect2, varscan2
- STRA8 | c.830C>A p.P277Q (on ENST00000275764; = p.P255Q on NM_182489.2) | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.804); catalogued as COSV51960994, COSV51962331; called by muse, mutect2, varscan2
- SULF1 | c.2040A>C p.Q680H | Missense Mutation (SNP) | VAF 88/149 reads (59%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.663); catalogued as COSV52687551; called by muse, mutect2, varscan2
- SYT16 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV70858084; called by muse, mutect2, varscan2
- SYT4 | c.1068G>T p.E356D | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV54902446; called by muse, mutect2, varscan2
- SZT2 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 77/86 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV100986830; called by muse, mutect2, varscan2
- TAS2R30 | c.440T>G p.I147R | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV67859302; called by muse, mutect2, varscan2
- TBC1D22A | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV61442470; called by muse, mutect2, varscan2
- TBC1D4 | c.3643G>T p.D1215Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66490407; called by muse, mutect2, varscan2
- TCEAL5 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV65503413; called by muse, mutect2, varscan2
- TCF20 | c.4720G>C p.E1574Q | Missense Mutation (SNP) | VAF 55/76 reads (72%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.966); catalogued as rs1435549844, COSV59494179, COSV59495841; called by muse, mutect2, varscan2
- TDRD7 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs765300189, COSV62430299, COSV62431032; called by muse, mutect2, varscan2
- TEF | c.173A>T p.K58M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV56748399; called by muse, mutect2
- TEKT4 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as COSV99726062; called by muse, mutect2, varscan2
- TENM2 | c.4233G>T p.Q1411H (on ENST00000518659 / NM_001122679.2; = p.Q1172H on NM_001080428.3) | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV69136176; called by muse, mutect2, varscan2
- TFG | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV52543975; called by muse, mutect2, varscan2
- TG | c.4772C>A p.S1591Y | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55086140; called by muse, mutect2, varscan2
- TG | c.8140G>T p.D2714Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55086170, COSV99602216; called by muse, mutect2, varscan2
- TGM1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as rs530095586, COSV52864266; called by muse, mutect2, varscan2
- THSD7B | c.2447G>T p.W816L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV55674015, COSV55713112; called by muse, mutect2, varscan2
- TLR10 | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV58301378; called by muse, mutect2, varscan2
- TMEM119 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as rs749087628, COSV67188995; called by muse, mutect2, varscan2
- TMEM132B | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV54761192; called by muse, mutect2, varscan2
- TMEM132D | c.1327C>A p.L443I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70614432, COSV70622696; called by muse, mutect2, varscan2
- TMEM132E | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV58698982; called by muse, mutect2, varscan2
- TMEM145 | c.961G>T p.G321* | Nonsense Mutation (SNP) | VAF 29/39 reads (74%) | catalogued as COSV56626560; called by muse, mutect2, varscan2
- TMEM71 | c.308T>C p.L103S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); catalogued as COSV63458334; called by muse, mutect2, varscan2
- TMTC2 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776775154, COSV58272778; called by muse, mutect2, varscan2
- TNFRSF4 | c.631G>T p.G211W | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV55420487; called by muse, varscan2
- TNFRSF8 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV55798620; called by muse, mutect2, varscan2
- TNNI3 | c.293G>C p.R98P | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM127301, COSV100787987, COSV61278309; called by muse, mutect2, varscan2
- TNR | c.1915G>T p.V639L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs752385367, COSV54900395; called by muse, mutect2, varscan2
- TOP2B | c.3129C>G p.F1043L (on ENST00000264331 / NM_001330700.2; = p.F1038L on NM_001068.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51968472, COSV51969786, COSV51974696; called by muse, varscan2
- TOPBP1 | c.2190A>T p.R730S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV53439066; called by muse, mutect2, varscan2
- TPH2 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61593068; called by muse, mutect2, varscan2
- TPO | c.541T>C p.Y181H | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61106291; called by muse, mutect2, varscan2
- TRAK2 | c.1837G>T p.D613Y | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60273636; called by muse, mutect2, varscan2
- TRAT1 | c.327C>A p.C109* | Nonsense Mutation (SNP) | VAF 20/112 reads (18%) | catalogued as COSV55469722; called by muse, mutect2, varscan2
- TRBV2 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs745705399; called by muse, mutect2, varscan2
- TRIM10 | c.1303C>G p.L435V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV64999539; called by muse, mutect2, varscan2
- TRIM50 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 27/101 reads (27%) | catalogued as COSV52721733, COSV99334038; called by muse, mutect2, varscan2
- TRIP6 | c.1002C>A p.A334= | Splice Region (SNP) | VAF 28/54 reads (52%) | catalogued as COSV52342545; called by muse, mutect2, varscan2
- TRPA1 | c.1507A>T p.K503* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | catalogued as COSV100082813; called by muse, mutect2, varscan2
- TRPC5 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53297362; called by muse, mutect2, varscan2
- TRPM1 | c.1055A>T p.Q352L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV99855158; called by muse, mutect2, varscan2
- TRPM1 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as rs1321586720, COSV99855163; called by muse, mutect2, varscan2
- TRPS1 | c.2088G>T p.Q696H (on ENST00000220888 / NM_001330599.2; = p.Q709H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as rs755741281, COSV55251716; called by muse, mutect2, varscan2
- TRPS1 | c.514G>T p.A172S (on ENST00000220888 / NM_001330599.2; = p.A185S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV55251733; called by muse, mutect2, varscan2
- TSHZ3 | c.3160C>A p.H1054N | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53676844; called by muse, mutect2, varscan2
- TSPEAR | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59951840, COSV59970899; called by muse, mutect2, varscan2
- TTC8 | c.1163A>G p.Y388C (on ENST00000338104 / NM_001288781.1; = p.Y372C on NM_144596.4) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1334256102, COSV57628864; called by muse, mutect2, varscan2
- TTF1 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.045); catalogued as COSV57505993; called by muse, mutect2, varscan2
- TTLL1 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56739609; called by muse, mutect2, varscan2
- TTN | c.75959C>A p.A25320E (on ENST00000591111; = p.A17896E on NM_003319.4) | Missense Mutation (SNP) | VAF 29/134 reads (22%) | PolyPhen benign (0.079); catalogued as rs749194310, COSV60198430; called by muse, mutect2, varscan2
- TTN | c.73883C>T p.S24628F (on ENST00000591111; = p.S17204F on NM_003319.4) | Missense Mutation (SNP) | VAF 56/274 reads (20%) | PolyPhen possibly damaging (0.735); catalogued as rs1438235594, COSV59909139, COSV60198457; called by muse, mutect2, varscan2
- TTN | c.70966G>T p.V23656F (on ENST00000591111; = p.V16232F on NM_003319.4) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | PolyPhen benign (0.021); catalogued as COSV60198485; called by muse, mutect2, varscan2
- TTN | c.66293T>C p.V22098A (on ENST00000591111; = p.V14674A on NM_003319.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | PolyPhen benign (0.169); catalogued as COSV60198514; called by muse, mutect2
- TTN | c.49232G>A p.G16411D (on ENST00000591111; = p.G8987D on NM_003319.4) | Missense Mutation (SNP) | VAF 93/212 reads (44%) | PolyPhen probably damaging (1); catalogued as COSV60198599; called by muse, mutect2, varscan2
- TTN | c.20167C>A p.R6723= (on ENST00000591111; = p.R5796= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 14/34 reads (41%) | catalogued as COSV59929700, COSV60198630; called by muse, mutect2, varscan2
- TTN | c.19127G>A p.G6376E (on ENST00000591111; = p.G5449E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | PolyPhen probably damaging (1); catalogued as COSV60198638, COSV60374536; called by muse, mutect2, varscan2
- TTN | c.11562G>T p.E3854D (on ENST00000591111; = p.E3808D on NM_003319.4) | Missense Mutation (SNP) | VAF 43/88 reads (49%) | catalogued as COSV60198655; called by muse, mutect2, varscan2
- TTN | c.10589C>A p.P3530H (on ENST00000591111; = p.P3484H on NM_003319.4) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV60198693; called by muse, varscan2
- TUBB1 | c.105C>A p.S35R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.022); catalogued as rs746670863, COSV53887579; called by muse, mutect2, varscan2
- TWNK | c.1358G>C p.R453P | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV52970028; called by muse, mutect2, varscan2
- UBAP2L | c.684T>G p.F228L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55177080; called by muse, mutect2, varscan2
- UBC | c.1977A>T p.E659D | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV60060392; called by muse, mutect2, varscan2
- UBE2E3 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66585703; called by muse, mutect2, varscan2
- UBL3 | c.281T>G p.L94* | Nonsense Mutation (SNP) | VAF 19/24 reads (79%) | catalogued as COSV66209882; called by muse, mutect2, varscan2
- UBR5 | c.6604G>T p.E2202* | Nonsense Mutation (SNP) | VAF 38/62 reads (61%) | catalogued as COSV55294082; called by muse, mutect2, varscan2
- UGT1A1 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV59393693; called by mutect2, varscan2
- UGT3A2 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV56932136; called by muse, mutect2, varscan2
- UMOD | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV56777688, COSV56779832; called by muse, mutect2, varscan2
- UNC13B | c.4246G>T p.V1416L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV61469885; called by muse, mutect2, varscan2
- UNC13C | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV52900080; called by muse, mutect2, varscan2
- UNC5D | c.1175C>A p.A392D | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV54814381; called by muse, mutect2, varscan2
- UNC79 | c.1688C>A p.T563N (on ENST00000393151 / NM_001346218.2; = p.T386N on NM_020818.5) | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); catalogued as COSV56398957; called by muse, mutect2, varscan2
- UNC80 | c.629G>T p.S210I | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); catalogued as COSV55897807, COSV55898660; called by muse, mutect2, varscan2
- USH2A | c.12110C>A p.T4037K | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56401532; called by muse, mutect2, varscan2
- USH2A | c.8876A>C p.Y2959S | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.455); catalogued as COSV56401549; called by muse, mutect2, varscan2
- USH2A | c.6612G>T p.M2204I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56401565; called by muse, mutect2, varscan2
- USP13 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55868429; called by muse, mutect2, varscan2
- USP13 | c.1408A>C p.S470R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.937); catalogued as COSV55868440; called by muse, mutect2, varscan2
- USP30 | c.914G>T p.R305M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57450171; called by muse, mutect2, varscan2
- VAMP4 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52560651, COSV52562154; called by muse, mutect2, varscan2
- VAX1 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143950742; called by muse, mutect2, varscan2
- VCAM1 | c.113A>T p.Q38L | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54120639; called by muse, mutect2, varscan2
- VCAN | c.3958C>A p.P1320T | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV54110912; called by muse, mutect2, varscan2
- VCPIP1 | c.2929G>T p.D977Y | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60049104; called by muse, mutect2, varscan2
- VNN2 | c.538T>G p.Y180D | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV58473343; called by muse, mutect2, varscan2
- VSIG2 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.982); catalogued as COSV52518418, COSV52519040; called by muse, mutect2, varscan2
- VSTM2A | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1209152826, COSV56495750; called by muse, mutect2, varscan2
- VWA3A | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774229691, COSV55391498; called by muse, mutect2, varscan2
- WDR12 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.474); catalogued as COSV53687970; called by muse, mutect2, varscan2
- WDR70 | c.297-1G>T p.X99_splice | Splice Site (SNP) | VAF 52/112 reads (46%) | catalogued as COSV54278488; called by muse, mutect2, varscan2
- WTIP | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV54329385; called by muse, mutect2, varscan2
- XIRP2 | c.1573C>A p.H525N (on ENST00000628543; = p.H700N on NM_152381.6) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV54692799; called by muse, mutect2, varscan2
- XIRP2 | c.3470A>G p.H1157R (on ENST00000628543; = p.H1332R on NM_152381.6) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54717662; called by muse, varscan2
- XPC | c.1227G>T p.Q409H | Missense Mutation (SNP) | VAF 107/132 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV53206351; called by muse, mutect2, varscan2
- ZC3H13 | c.653C>G p.S218C | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54458995; called by muse, mutect2, varscan2
- ZDBF2 | c.7028G>A p.R2343Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1456131206, COSV65622999; called by muse, mutect2, varscan2
- ZDHHC17 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs762423098, COSV58352937; called by muse, mutect2, varscan2
- ZDHHC23 | c.568A>T p.K190* | Nonsense Mutation (SNP) | VAF 27/196 reads (14%) | catalogued as COSV57629959; called by muse, mutect2, varscan2
- ZFAT | c.1361A>C p.H454P | Missense Mutation (SNP) | VAF 76/97 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64742216; called by muse, mutect2, varscan2
- ZFHX4 | c.4435G>T p.D1479Y | Missense Mutation (SNP) | VAF 51/72 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV51474069, COSV51493490; called by muse, mutect2, varscan2
- ZFHX4 | c.7976G>T p.R2659L | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51474147, COSV99270158; called by muse, mutect2, varscan2
- ZFHX4 | c.8275A>G p.T2759A | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); catalogued as COSV51474210; called by muse, mutect2, varscan2
- ZFHX4 | c.10348C>A p.L3450I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as COSV50753577, COSV50865058; called by muse, mutect2, varscan2
283 further variants in this file (55 protein-altering or splice-affecting, 211 silent, 17 other) are not listed here.
